FM case AD17491 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/45fbe30a-a6f1-4740-bd63-0ceddaa8c29c

Male, 55.0 years: Carcinoma, NOS (ICD-O-3 8010/3) of the pancreas; metastasis. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
